Gene-level copy-number profile of tumor specimen ALCH-B2X7-TTP1-A from ALCHEMIST case ALCH-B2X7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.0 years (27,410 days).
Specimen ALCH-B2X7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb3d6395-ba97-481f-829b-438e9ce4787b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2X7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/00371250-374f-4f9d-ab45-0973204f1bdb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,541; copy number 2: 50,340; copy number 3: 4,683; copy number 4: 321; copy number 5: 207; copy number 6: 158; copy number 7: 22; copy number 8: 40; copy number 9: 46; copy number 10: 7; copy number 11: 4; copy number 15: 23.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:9,899,871–9,906,678, 2 genes: MIR124-1HG, MIR124-1.
- chr11:47,331,406–47,352,702, 1 gene: MYBPC3.
- chr19:19,512,418–19,546,659, 5 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 504 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,583,510–1,583,909, 1 gene, copy number 5: AL691432.3.
- chr5:612,340–1,345,099, 24 genes, copy number 8: CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:6,839,460–7,219,291, 1 gene, copy number 6 (within-gene range 2–6): LINC02196.
- chr5:7,047,227–7,391,907, 11 genes, copy number 6: RNA5SP176, AC025756.1, Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:10,057,502–10,556,815, 31 genes, copy number 6: AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1.
- chr5:12,553,890–13,190,677, 6 genes, copy number 6: AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1.
- chr5:148,088,125–148,677,235, 15 genes, copy number 6 (within-gene range 2–6): AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1.
- chr5:150,846,523–151,655,449, 23 genes, copy number 6: IRGM, ZNF300, ZNF300P1, AC022106.1, AC022106.2, GPX3, TNIP1, ANXA6, AC008641.1, CCDC69, GM2A, SLC36A3, SLC36A2, ATP6V1G1P5, AC034205.2, AC034205.1, AC034205.3, SLC36A1, RNA5SP197, FAT2, AC011337.1, MIR6499, AC011374.1.
- chr5:155,397,291–160,345,396, 79 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr5:173,254,190–174,330,503, 23 genes, copy number 8–10: Y_RNA, RNA5SP200, STC2, MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, LINC01485, CPEB4, C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1.
- chr5:181,205,361–181,248,096, 6 genes, copy number 7 (within-gene range 2–7): AC008443.3, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A.
- chr8:46,549,089–49,076,093, 58 genes, copy number 5: HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL.
- chr11:27,506,830–27,698,231, 1 gene, copy number 5 (within-gene range 3–5): BDNF-AS.
- chr11:27,617,626–28,527,041, 12 genes, copy number 5 (within-gene range 3–5): LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1.
- chr12:56,822,985–59,064,238, 86 genes, copy number 5 (broad region; genes not listed).
- chr12:61,231,159–62,935,150, 23 genes, copy number 5 (within-gene range 4–5): AC090017.1, DUX4L52, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P.
- chr12:64,186,316–64,222,296, 2 genes, copy number 6: C12orf66, RNU6-1009P.
- chr12:67,571,197–68,971,570, 40 genes, copy number 7–15: LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,326,574–73,143,858, 58 genes, copy number 5–6: AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 2,540. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
